Somatic mutation profile of tumor specimen TCGA-EL-A3H8-01A (aliquot TCGA-EL-A3H8-01A-11D-A20C-08) from TCGA case TCGA-EL-A3H8, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 35.6 years (12,992 days).
Specimen TCGA-EL-A3H8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 20b5c0a1-efe9-4df6-bc18-4abc96b92aa7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EL-A3H8-10A (Blood Derived Normal), aliquot TCGA-EL-A3H8-10A-01D-A20C-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b4c00ab4-55ea-4c7f-8ecb-53b0b517ebd4

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 5, Nonsense Mutation 2, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CACNA1E | c.4868T>C p.I1623T | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62381336; called by muse, mutect2, varscan2
- CEP95 | c.379C>T p.Q127* | Nonsense Mutation (SNP) | VAF 16/49 reads (33%) | catalogued as rs782306825, COSV73608538; called by muse, mutect2, varscan2
- DNAH2 | c.13110C>A p.S4370R | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as COSV66715963; called by muse, mutect2, varscan2
- LRP1B | c.9190C>T p.R3064* | Nonsense Mutation (SNP) | VAF 8/120 reads (7%) | catalogued as COSV67183688; called by muse, mutect2
- SNAP47 | c.254G>A p.S85N | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.098); catalogued as COSV59916800; called by muse, mutect2
- UROC1 | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 16/204 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.425); catalogued as rs369545977; called by muse, mutect2
- FUNDC2 | c.550C>T p.L184= | Silent (SNP) | VAF 18/379 reads (5%) | catalogued as COSV65670322, COSV65670422, COSV65671283; called by muse, mutect2
- ZAN | c.6363G>A p.Q2121= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as rs1454311265; called by muse, mutect2
